Gene-level copy-number profile of tumor specimen TCGA-DK-A3IV-01A from TCGA case TCGA-DK-A3IV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.9 years (22,237 days).
Specimen TCGA-DK-A3IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.dc230187-0e08-495a-90d8-7d78ec2d3e5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9394171-4e35-4c10-84df-7cb85c586131

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 13,532; copy number 2: 39,770; copy number 3: 4,796; copy number 4: 678; copy number 5: 44; copy number 6: 714; copy number 7: 45; copy number 8: 2; copy number 9: 63; copy number 16: 3; copy number 17: 2; copy number 33: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IV-01A-22D-A219-01): tumor purity 0.56, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:76,747,719–77,593,319, 1 gene (within-gene range 0–1): LRRTM4.
- chr2:77,210,587–84,040,720, 55 genes: AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 910 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:194,091,561–194,260,720, 6 genes, copy number 6 (within-gene range 2–6): AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037.
- chr4:57,841,721–57,855,271, 1 gene, copy number 8: AC104790.1.
- chr5:125,966,777–125,968,085, 1 gene, copy number 9: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene, copy number 6: AC008725.1.
- chr6:51,385,282–51,385,849, 1 gene, copy number 5: AL158050.2.
- chr7:12,726,152–13,751,920, 1 gene, copy number 6 (within-gene range 2–6): AC011287.1.
- chr7:13,339,201–20,415,754, 78 genes, copy number 6 (broad region; genes not listed).
- chr7:23,298,739–24,981,634, 32 genes, copy number 5 (within-gene range 2–5): MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19.
- chr7:76,818,377–76,903,041, 1 gene, copy number 5 (within-gene range 2–5): AC006972.1.
- chr7:126,495,312–126,531,336, 2 genes, copy number 5 (within-gene range 2–5): AC002057.2, AC000374.1.
- chr11:21,383,801–21,383,909, 1 gene, copy number 9: RNA5SP337.
- chr11:50,409,042–50,422,316, 1 gene, copy number 8: AC024405.1.
- chr12:28,505,394–28,505,528, 1 gene, copy number 9: RNA5SP355.
- chr12:46,764,761–46,832,408, 1 gene, copy number 5 (within-gene range 2–5): SLC38A4.
- chr14:21,887,857–21,924,651, 5 genes, copy number 5: TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4.
- chr16:19,113,932–34,965,270, 628 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:52,198,012–52,227,956, 1 gene, copy number 5 (within-gene range 1–5): AC007333.2.
- chr18:29,048,620–29,048,719, 1 gene, copy number 5: RNU6-408P.
- chr20:31,257,664–35,147,336, 147 genes, copy number 7–33 (within-gene range 3–33) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,479. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
